CCDI case PBBXFV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/80c53afe-b42f-406c-a0fe-0176d01baee3

Demographics
Sex at birth: female.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 4.3 years (1,555 days).

Biospecimens (3 samples)
- Sample 0DJQZE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJR0U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJR21: Tissue type: Tumor; Specimen type: Solid Tissue.
